Gene-level copy-number profile of tumor specimen TCGA-E7-A7DV-01A from TCGA case TCGA-E7-A7DV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 44.2 years (16,145 days).
Specimen TCGA-E7-A7DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f221d5e1-7f30-4b8c-9b81-6338140c50c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A7DV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ab6a42d-7f7e-4339-a16c-ae199e974a61

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,812; copy number 2: 21,198; copy number 3: 22,779; copy number 4: 7,290; copy number 5: 3,114; copy number 6: 1,783; copy number 7: 745; copy number 8: 283; copy number 9: 130; copy number 10: 159; copy number 11: 116; copy number 12: 46; copy number 13: 57; copy number 14: 100; copy number 15: 1; copy number 17: 31; copy number 18: 50; copy number 19: 9; copy number 20: 19; copy number 25: 65; copy number 26: 4; copy number 28: 16; copy number 33: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A7DV-01A-11D-A338-01): tumor purity 0.35, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,787 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,896,809–7,741,533, 23 genes, copy number 7 (within-gene range 5–7): BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1.
- chr5:58,198–3,181,487, 87 genes, copy number 8 (broad region; genes not listed).
- chr5:50,396,192–50,903,743, 7 genes, copy number 13–28: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3.
- chr6:19,290,319–23,031,780, 41 genes, copy number 9–28 (within-gene range 3–28): AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1.
- chr6:30,451,139–30,792,250, 29 genes, copy number 11: AL662873.1, TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P.
- chr7:16,916,359–17,467,256, 8 genes, copy number 9 (within-gene range 5–9): AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr8:42,151,772–43,363,518, 41 genes, copy number 7–25 (within-gene range 1–25): AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8.
- chr8:82,033,533–89,415,071, 86 genes, copy number 7–12 (broad region; genes not listed).
- chr8:100,776,512–145,066,685, 685 genes, copy number 7–20 (broad region; genes not listed).
- chr9:24,542,952–25,089,151, 4 genes, copy number 7: IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr9:29,317,833–33,264,720, 47 genes, copy number 9: AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1.
- chr9:35,906,202–37,120,446, 33 genes, copy number 10: HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2.
- chr9:37,160,137–37,160,237, 1 gene, copy number 10: Y_RNA.
- chr9:88,066,445–94,301,829, 134 genes, copy number 10–20 (broad region; genes not listed).
- chr10:44,712–2,618,739, 40 genes, copy number 7–11 (within-gene range 5–11): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1, AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1.
- chr11:39,024,631–39,261,213, 3 genes, copy number 7 (within-gene range 2–7): AC021723.2, AC021723.1, RNU6-99P.
- chr11:59,978,020–60,184,666, 7 genes, copy number 7 (within-gene range 4–7): OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A.
- chr11:60,200,270–60,243,137, 2 genes, copy number 7 (within-gene range 4–7): MS4A4E, MIR6503.
- chr11:97,657,464–100,358,885, 10 genes, copy number 7–15: RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3.
- chr11:101,451,564–101,872,562, 1 gene, copy number 11 (within-gene range 5–17): TRPC6.
- chr11:101,765,935–102,001,062, 3 genes, copy number 17 (within-gene range 6–17): AP000776.1, ANGPTL5, CEP126.
- chr11:102,396,332–105,123,339, 53 genes, copy number 18–33 (within-gene range 6–33): TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1.
- chr11:105,194,440–105,247,060, 2 genes, copy number 12: OR2AL1P, AP003181.1.
- chr11:105,974,826–112,963,460, 142 genes, copy number 8–25 (broad region; genes not listed).
- chr11:112,977,353–112,977,420, 1 gene, copy number 8: RNU7-187P.
- chr12:46,004,038–46,373,778, 5 genes, copy number 7: AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,652,550, 5 genes, copy number 7 (within-gene range 5–7): AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P.
- chr19:27,638,483–29,901,869, 53 genes, copy number 7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1.
- chr19:53,775,599–55,487,568, 147 genes, copy number 7 (broad region; genes not listed).
- chr19:56,669,941–58,155,110, 87 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
